Somatic mutation profile of tumor specimen MP2PRT-PAPXNH-TMP1-A (aliquot MP2PRT-PAPXNH-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPXNH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,907 days).
Specimen MP2PRT-PAPXNH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e6e0a86-aab2-4dc7-a8f4-fcd966a1fddc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXNH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXNH-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a10a508-fb2b-4e01-9d02-8228ef10cb95

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H1-2 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs200705328; called by muse, mutect2, varscan2
- LRBA | c.7415G>A p.R2472Q | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.301); catalogued as COSV63949907; called by muse, mutect2, varscan2
- NKAPL | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 161/397 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.226); catalogued as rs776973377, COSV59197319; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFM1 | c.1232C>T p.T411M (on ENST00000371793 / NM_001282611.2; = p.T393M on NM_014279.5) | Missense Mutation (SNP) | VAF 168/477 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767622547, COSV53277197, COSV53278980; called by muse, mutect2, varscan2
- PRKCE | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 161/433 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV60324784; called by muse, varscan2
- IGKV1D-8 | c.346_352del p.F116_P117del | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by pindel*, varscan2
- LOXHD1 | c.2177A>T p.N726I | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- NCKAP1 | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NUBPL | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2
- RBM24 | c.239A>C p.K80T (on ENST00000379052 / NM_001143942.2; = p.K35T on NM_153020.2) | Missense Mutation (SNP) | VAF 126/325 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UBA7 | c.746_747insGAATACTTGCG p.G250Nfs*17 | Frame Shift Ins (INS) | VAF 64/243 reads (26%) | called by mutect2, varscan2
- APBB2 | c.150C>T p.N50= | Silent (SNP) | VAF 126/355 reads (35%) | catalogued as rs751805016; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 99/352 reads (28%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- IGSF22 | c.540G>A p.K180= | Silent (SNP) | VAF 113/325 reads (35%) | called by muse, mutect2, varscan2
- JOSD1 | c.174G>A p.E58= | Silent (SNP) | VAF 71/206 reads (34%) | called by muse, mutect2, varscan2
- LAMA1 | c.5820C>T p.N1940= | Silent (SNP) | VAF 92/246 reads (37%) | catalogued as rs368850544; called by muse, mutect2, varscan2
- PADI6 | c.189G>A p.T63= | Silent (SNP) | VAF 129/423 reads (30%) | catalogued as rs373763933; called by muse, mutect2, varscan2
- PCARE | c.2691C>T p.T897= | Silent (SNP) | VAF 163/951 reads (17%) | catalogued as rs767685634, COSV59054838; called by muse, mutect2, varscan2
- G3BP1 | chr5:151770644 C>T | 5'Flank (SNP) | VAF 28/600 reads (5%) | catalogued as rs1239483709; called by muse, mutect2
- TRGV5 | chr7:38353714 ins TTGGA | 5'Flank (INS) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
